FM case AD15305 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Ureter.
https://portal.gdc.cancer.gov/cases/56f2eef5-ae4b-418c-b5b8-51b1d5173847

Male, 60.6 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the ureter; primary biopsied or resected from the ureter. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
